Gene-level copy-number profile of tumor specimen TCGA-58-8392-01A from TCGA case TCGA-58-8392, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.4 years (25,710 days).
Specimen TCGA-58-8392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d2eeeefe-971b-4eef-9180-163300fc9d27.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-8392-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/66a82e70-d69e-4760-975e-88e632dc8c5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 21,968; copy number 2: 32,294; copy number 3: 4,239; copy number 4: 662; copy number 5: 21; copy number 6: 76; copy number 7: 33; copy number 9: 91; copy number 10: 210; copy number 12: 140; copy number 15: 25.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,532,145–10,777,525, 4 genes: AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1.
- chr9:21,160,235–22,455,740, 50 genes: Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 596 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:163,026,396–185,191,955, 346 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr7:52,493,152–62,275,678, 174 genes, copy number 9–15 (broad region; genes not listed).
- chr20:8,831,186–13,996,443, 67 genes, copy number 6 (broad region; genes not listed).
- chr20:14,003,508–14,758,056, 9 genes, copy number 6: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2.

Autosomal genes at a single copy (total copy number 1): 19,558. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
